Somatic mutation profile of tumor specimen 0DQU4W from CCDI case PBCFNC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,283 days).
Specimen 0DQU4W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fd94833-40a3-435d-aca2-b1a00243f1ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQU5D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42e40eca-eade-4d34-9ec4-581e4d96ba8c

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, 5'UTR 3, Intron 2, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 171/517 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3577G>T p.D1193Y | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55289396; called by muse, mutect2
- BCOR | c.4540C>T p.R1514* (on ENST00000378444 / NM_001123385.2; = p.R1480* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 144/507 reads (28%) | catalogued as CM0910704, COSV60703956, COSV60716852; called by muse, mutect2, varscan2
- BGLAP | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 114/626 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs770037751, COSV99431499; called by muse, mutect2, varscan2
- CDH23 | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 94/500 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs765527342, COSV56448965; called by muse, mutect2, varscan2
- CHD3 | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100391129; called by muse, mutect2
- COG7 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs764153683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A2 | c.5170C>T p.R1724W (on ENST00000341947 / NM_080680.3; = p.R1617W on NM_080679.2) | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs762351406, COSV59493447; ClinVar: uncertain significance; called by muse, mutect2
- HECW1 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 75/609 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1369793479, COSV67821067; called by muse, mutect2, varscan2
- MED12 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61329305, COSV61331528; called by muse, mutect2, varscan2
- MUC16 | c.43238G>A p.R14413Q | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.129); catalogued as rs781208702, COSV66691218; called by muse, mutect2, varscan2
- SNAPC4 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs761653938, COSV53732412; called by muse, mutect2, varscan2
- STIP1 | c.1217A>G p.K406R | Missense Mutation (SNP) | VAF 106/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1040438858; called by muse, mutect2, varscan2
- STX3 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.19); catalogued as COSV55696366; called by muse, mutect2
- DLEC1 | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 130/362 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- GAA | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 166/724 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PLXNA3 | c.5307C>A p.D1769E | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMS | c.1065G>T p.W355C | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMYM3 | c.4069A>T p.I1357F | Missense Mutation (SNP) | VAF 90/519 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CELSR3 | c.7953C>T p.G2651= | Silent (SNP) | VAF 71/486 reads (15%) | catalogued as rs760257509, COSV50855210; called by muse, mutect2, varscan2
- IQSEC1 | c.138C>T p.P46= | Silent (SNP) | VAF 92/384 reads (24%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.2205C>T p.S735= | Silent (SNP) | VAF 24/462 reads (5%) | catalogued as COSV53936832; called by muse, mutect2
- PRSS35 | c.1218C>T p.N406= | Silent (SNP) | VAF 80/288 reads (28%) | catalogued as rs370535612; called by muse, mutect2, varscan2
- GGT1 | c.1021-42del | Intron (DEL) | VAF 4/30 reads (13%) | catalogued as rs779615105; called by mutect2, pindel
- PADI1 | c.1632+73T>C | Intron (SNP) | VAF 7/175 reads (4%) | catalogued as rs914542162; called by muse, mutect2
- PDZD4 | c.*9G>A | 3'UTR (SNP) | VAF 29/215 reads (13%) | catalogued as COSV99381346; called by muse, mutect2, varscan2
- PKIG | c.-7G>A | 5'UTR (SNP) | VAF 23/396 reads (6%) | catalogued as rs199704290; called by muse, mutect2
- SLAMF6 | c.-8C>T | 5'UTR (SNP) | VAF 41/281 reads (15%) | catalogued as rs200834145; called by muse, mutect2, varscan2
- TAZ | c.-68C>T | 5'UTR (SNP) | VAF 32/126 reads (25%) | called by muse, mutect2, varscan2
- TNFSF12 | c.*3G>C | 3'UTR (SNP) | VAF 22/456 reads (5%) | called by muse, mutect2
